Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9JV, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9JV-01A (Primary Tumor).

ICD-O-3
Carcinoma, papillary renal cell
Site: (L) Kidney C64.9
826013
6/13/14

1 and 2. Papillary Renal Cell Carcinoma

TNM Classification: Malignant tumor (version 2002), pT1a, GII

Laterality = (L)

Source: NCI Genomic Data Commons file ef10c7e5-f12f-404a-b2a6-ec5504936b4c (TCGA-5P-A9JV.3B9C37B5-FDEF-40B8-911E-610B3EA99D7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).